Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A1OA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A1OA-01A (Primary Tumor).

[page 1 of 3]
S

PATHOLOGY REPORT

PATIENT: [REDACTED]

Hospital No.:
Date of Birth:
Soc. Sec. No:
Location:

Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 3/4/11 lw

DIAGNOSIS:

1. LEFT ADNEXA:

- Benign ovary with involutional changes
- Minute inclusion cyst, ovarian cortex
- Unremarkable fallopian tube
- Minute paratubal cyst (hydatid of Morgagni)

2. RIGHT ADNEXA:

- Benign ovary with involutional changes
- Unremarkable fallopian tube
- Paratubal cysts (hydatids of Morgagni)

3. UTERUS, RATIFIED RADICAL HYSTERECTOMY:

- Invasive non-keratinizing squamous cell carcinoma
- Moderately to poorly differentiated
- The maximal thickness of cervical stromal invasion is 31 mm
- The thickness of the cervix in the area of maximal invasion is 36 mm
- The maximal width of tumor is 15 mm
- Multifocal angiolymphatic invasion identified
- Multifocal invasion of lymphatic vessels in the vaginal cuff with no evidence of direct tumor invasion
- Multifocal lymphatic invasion in the anterior and posterior uterine corpus
- No evidence of tumor seen in sections of upper uterine corpus
- No parametrial involvement is identified
- Modified FIGO stage IB
- No diagnostic findings:
- Benign atrophic endometrium
- Unremarkable myometrium

4,5. RIGHT AND LEFT PELVIC LYMPH NODES:

- A total of eight lymph nodes identified, all of them exhibiting extensive presence of metastatic carcinoma (8/8)

HISTORY: Cervical cancer, squamous cell carcinoma.

MICROSCOPIC:

See Diagnosis.

GROSS:

1. LEFT ADNEXA

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 3.4 x 0.4 x 0.4 cm segment of fallopian tube, with an attached ovary measuring 2.8 x 0.9 x 0.8 cm. The ovary is yellow tan with a

[page 2 of 3]
smooth external surface, and a homogeneous fibrous parenchyma. There are 5 clear serous peritubal cyst ranging in size from 0.1, up to 0.3 cm in greatest dimension. Representative sections.
A: 2

2. RIGHT ADNEXA

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 3.8 x 0.6 x 0.6 cm segment of fallopian tube, with an attached ovary measuring 2.8 x 1.2 x 0.6 cm. The ovary is yellow tan with a smooth external surface, and a homogeneous fibrous parenchyma. There are 3 clear serous peritubal cysts, ranging in size from 0.2, up to 0.7 cm in dimension. Representative sections.
B: 2

3. CERVIX UTERUS

Labeled with the patient's name, designated "uterus" and received in the fresh state in the Operating Room for intra-operative gross consultation and subsequently fixed in formalin is a 50 g uterus and attached cervix, measuring 7.2 cm from superior to inferior, 4.2 cm from cornu to cornu, and 2.5 cm from anterior posterior. There is an attached vaginal cuff ranging in length from 0.9, up to 2.1 cm in length. The exocervix measures approximately 2.4 x 2.3 cm, and has a incomplete, distinct zone of transformation. The serosal surface of the uterus is smooth and pink tan. Opening the uterus reveals an intrauterine cavity measuring 1.5 cm from cornu of the cornu and 2.3 cm from superior to inferior. The myometrium measures 1.4 cm in maximum thickness, the endometrium measures less than 0.1 cm in greatest thickness. The endocervical canal measures approximately 2.4 cm in length. The wall of the cervical neck is firm with a homogeneous white-tan parenchyma, consistent with transmural replacement by tumor, from the transformation zone, to the lower uterine segment. Myometrium of the remaining uterine corpus is grossly unremarkable. Representative sections.

C-D: anterior cervix bisected-1
E-F: posterior cervix bisected-1
G: lower anterior uterine corpus-1
H: lower posterior lower uterine corpus-1
I: upper anterior uterine corpus-1
J: upper posterior uterine corpus-1
K: right parametrial tissue-1
L: left parametrial tissue-1

4. RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are 2 grossly positive lymph nodes measuring 2.8 x 2.2 x 1.5, and 1.4 x 0.9 x 0.8 cm. Also received in the specimen container are 3 irregular variegated tan-brown these of tissue ranging in size from 0.6, up to 1.8 cm in greatest dimension. Dissection yields no other lymph nodes. Representative sections.

M,N: larger lymph node bisected-1 each
O: smaller lymph node bisected-2

5. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 1.4 x 0.9 x 0.8 cm grossly positive lymph node. Also received in the specimen container is a 3.0 x 1.4 x 0.6 cm piece of fatty tissue. Dissection reveals 4 possible lymph nodes. Entirely submitted.

P: grossly positive lymph node bisected-2
Q: lymph node bisected-2
R: lymph node bisected-2
S: lymph node bisected-2
T: lymph node bisected-2

Gross dictated by

[page 3 of 3]
OPERATIVE CONSULT (GROSS):

(#3) Cervical carcinoma, grossly involving full thickness of the cervical wall. No parametrial cervical vaginal extension grossly. A small piece of tumor given to Dr.

Special Studies: None
See Also:

Pathologist

I, _____, M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.
Date Finalled:

Source: NCI Genomic Data Commons file c02c96b8-984d-4f37-8d03-a2f8bb6c9570 (TCGA-DS-A1OA.A2FAE559-D2B2-4132-9B16-37E677C1B09A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).